Somatic mutation profile of tumor specimen TCGA-CQ-A4C9-01A (aliquot TCGA-CQ-A4C9-01A-11D-A25D-08) from TCGA case TCGA-CQ-A4C9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Anterior floor of mouth; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 56.8 years (20,732 days).
Specimen TCGA-CQ-A4C9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7f68cc2-5a42-4e66-bf79-87097056f183.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-A4C9-10A (Blood Derived Normal), aliquot TCGA-CQ-A4C9-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c719e06d-5482-4141-9e6c-d2f56fd14535

The open-access MAF lists 92 somatic variants for this specimen: 66 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 23, Intron 3, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs769569410, CM060776, COSV100216536; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- H3C3 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV63550964, COSV63551270; called by muse, mutect2, varscan2
- TP53 | c.536A>T p.H179L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AADACL3 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs868224597, COSV100206531; called by muse, mutect2, varscan2
- ADPRHL1 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV100733339; called by muse, mutect2
- ALG1L | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs368430945; called by muse, mutect2, varscan2
- ARL5A | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV54469871, COSV99706730; called by mutect2, varscan2
- ASIC3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs766867558, COSV52506900; called by muse, mutect2, varscan2
- ATP2C1 | c.1469G>A p.C490Y | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM020633, COSV100146213; called by muse, mutect2, varscan2
- BEND2 | c.1949C>A p.T650N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV101191748; called by muse, mutect2, varscan2
- C14orf119 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV52975555; called by mutect2, varscan2
- CALM2 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV99700581, COSV99700595; called by muse, mutect2
- CAPSL | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs756156534, COSV68438018; called by muse, mutect2, varscan2
- CHD7 | c.8875G>A p.E2959K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.905); catalogued as rs774166245, COSV101417967; called by muse, mutect2, varscan2
- CKMT1B | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as rs377050601; called by muse, mutect2
- COTL1 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749367597, COSV52289491, COSV52290276; called by muse, mutect2, varscan2
- CYP2C8 | c.978G>T p.E326D | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64877389, COSV64879136; called by muse, mutect2, varscan2
- CYP7A1 | c.298T>A p.F100I | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs777813512, COSV100052122; called by muse, mutect2
- DOCK11 | c.830G>A p.S277N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as rs747676019, COSV99352759; called by muse, mutect2, varscan2
- EEF2KMT | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV101435293; called by muse, mutect2, varscan2
- FGF9 | c.242C>G p.T81S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV101210923; called by muse, mutect2, varscan2
- GPR37 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as COSV58258464, COSV58259159; called by muse, mutect2, varscan2
- GRM8 | c.510+1G>T p.X170_splice | Splice Site (SNP) | VAF 12/94 reads (13%) | catalogued as COSV58813685; called by muse, mutect2, varscan2
- HEATR6 | c.2860G>C p.E954Q | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); catalogued as COSV51745022; called by muse, mutect2
- IFNAR1 | c.1441T>C p.Y481H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV99531448; called by muse, mutect2, varscan2
- KCNH4 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV99236703; called by muse, mutect2, varscan2
- KCNK13 | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56417781, COSV99965478; called by muse, mutect2, varscan2
- KPRP | c.1364G>C p.C455S | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.295); catalogued as COSV100908655, COSV64222934; called by muse, mutect2, varscan2
- LAMA2 | c.8734A>C p.N2912H | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101369898; called by muse, mutect2, varscan2
- LAMB1 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99739756; called by muse, mutect2
- LMAN1L | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100547530; called by muse, mutect2, varscan2
- LMOD2 | c.1218A>T p.K406N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); catalogued as COSV101505401; called by muse, mutect2
- MCOLN2 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99393564; called by muse, mutect2, varscan2
- MME | c.2218T>C p.Y740H | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.047); catalogued as COSV100852215; called by muse, mutect2, varscan2
- MTUS2 | c.3043G>A p.A1015T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV101462058; called by muse, mutect2, varscan2
- MYO18B | c.7448C>A p.S2483Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV100122485; called by muse, mutect2, varscan2
- NOL4 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.123); catalogued as rs776824670, COSV99304843; called by muse, mutect2, varscan2
- NXPH3 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1239360769, COSV100165444; called by muse, mutect2, varscan2
- OR2T12 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58778277; called by muse, mutect2, varscan2
- PSAP | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV101206418; called by muse, mutect2, varscan2
- PTCHD3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.3); catalogued as rs757465209, COSV71256730; called by muse, mutect2, varscan2
- RABGAP1L | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99051363, COSV99267284; called by muse, mutect2, varscan2
- RBBP7 | c.692A>T p.D231V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100417808; called by muse, mutect2, varscan2
- RELN | c.8029G>A p.A2677T | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.356); catalogued as rs747571208, COSV58987976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC23IP | c.699T>G p.V233= | Splice Region (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100956735; called by muse, mutect2, varscan2
- SETD1A | c.913T>A p.Y305N | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as COSV99352348; called by muse, mutect2, varscan2
- SLC35F1 | c.197T>A p.L66Q | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100837473; called by muse, mutect2
- SLC8A1 | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60479171, COSV60497582; called by muse, mutect2, varscan2
- SNRNP40 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.99); catalogued as COSV99745016; called by muse, mutect2, varscan2
- SOX17 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV99810340; called by muse, mutect2
- SPATA12 | c.83G>C p.R28T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100534641; called by muse, mutect2, varscan2
- SPICE1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 4/95 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV55619004; called by muse, mutect2
- TMEM131 | c.4148A>G p.K1383R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV99486413; called by muse, mutect2, varscan2
- TMEM94 | c.2033G>T p.R678L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.995); catalogued as COSV100050067; called by muse, mutect2, varscan2
- TRPC4AP | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99327733; called by muse, mutect2
- VAV1 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as rs761409372, COSV100408566; called by muse, mutect2, varscan2
- WRN | c.4199C>T p.S1400F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV99988187; called by muse, mutect2, varscan2
- ZMYM6 | c.3660G>A p.M1220I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs753406108, COSV100592994; called by muse, mutect2, varscan2
- ZNF780A | c.1904A>T p.H635L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100574936; called by muse, mutect2, varscan2
- CNBD1 | c.1230del p.V411Ffs*36 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- FAT2 | c.3696C>G p.I1232M | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2
- FAT3 | c.6962T>A p.M2321K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.034); called by mutect2, varscan2
- FAT3 | c.7490C>T p.S2497L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.441); called by muse, mutect2
- PRAMEF20 | c.1216A>T p.N406Y | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TRAPPC13 | c.862del p.R288Gfs*30 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- TRGV4 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.082); called by muse, mutect2
- ABTB1 | c.711C>T p.L237= (on ENST00000232744 / NM_172027.3; = p.L95= on NM_032548.3) | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV51742884; called by muse, mutect2
- AC245033.1 | c.1518G>C p.L506= | Silent (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- ACOX2 | c.1542A>G p.S514= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100249966; called by muse, mutect2, varscan2
- AMOTL2 | c.918G>A p.S306= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs531492024, COSV99997961; called by muse, mutect2, varscan2
- ATP4A | c.2904C>T p.I968= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs374197390; called by muse, varscan2
- BTNL3 | c.495C>T p.A165= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100732166; called by muse, mutect2, varscan2
- CMYA5 | c.2161T>C p.L721= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV101483792; called by muse, mutect2, varscan2
- EIF2A | c.705G>A p.V235= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs891862280, COSV99855718; called by muse, mutect2, varscan2
- KIF4B | c.501T>C p.P167= | Silent (SNP) | VAF 26/147 reads (18%) | catalogued as COSV101469187; called by muse, mutect2, varscan2
- KMT2A | c.10278C>T p.I3426= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as COSV100627880; called by muse, mutect2
- LTBP2 | c.477G>A p.P159= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV56213897; called by muse, mutect2, varscan2
- MOB2 | c.525C>G p.L175= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs1195526976, COSV100326430, COSV57319299; called by muse, mutect2, varscan2
- MUC3A | c.67T>C p.L23= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV100113852; called by muse, mutect2, varscan2
- NBAS | c.6756G>A p.L2252= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99866890; called by muse, mutect2, varscan2
- PLCB1 | c.2457G>A p.L819= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV62037999; called by muse, mutect2
- SATB2 | c.1344C>T p.V448= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV99610488; called by muse, mutect2, varscan2
- SH3TC1 | c.3648C>T p.L1216= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1258983093, COSV99794345; called by muse, mutect2, varscan2
- SLCO1C1 | c.1299C>G p.V433= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV99858414; called by muse, mutect2, varscan2
- VPS33A | c.819G>A p.Q273= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV99931186; called by muse, mutect2, varscan2
- WDR49 | c.1629A>G p.E543= (on ENST00000308378 / NM_001366158.1; = p.E884= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100391484, COSV57705261; called by muse, mutect2, varscan2
- WNT2 | c.42G>T p.L14= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99625671; called by muse, mutect2, varscan2
- ZFPM2 | c.2535G>A p.T845= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs772013671, COSV65873107; called by muse, varscan2
- ZNF536 | c.1239G>A p.V413= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100834579; called by muse, mutect2, varscan2
- ELAVL2 | c.-12-2769G>A | Intron (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99805266; called by muse, mutect2
- NRXN3 | c.602-5453C>A | Intron (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99815472; called by muse, mutect2
- TRIP12 | c.99-901C>G | Intron (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99389206; called by muse, mutect2, varscan2
